Somatic mutation profile of tumor specimen TCGA-BQ-7053-01A (aliquot TCGA-BQ-7053-01A-11D-1961-08) from TCGA case TCGA-BQ-7053, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 57.0 years (20,837 days).
Specimen TCGA-BQ-7053-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7c317d3a-2d33-46d7-be90-7836687305a2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BQ-7053-11A (Solid Tissue Normal), aliquot TCGA-BQ-7053-11A-01D-1961-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/00664dfb-18e7-44b0-b9be-c5912be41376

The open-access MAF lists 56 somatic variants for this specimen: 43 protein-altering or splice-affecting, 9 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 9, Nonsense Mutation 5, Frame Shift Del 5, Intron 1, 5'UTR 1, In Frame Del 1, 3'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA7 | c.5527G>A p.D1843N | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.906); catalogued as rs755914271, COSV54025866, COSV99566961; called by muse, mutect2, varscan2
- ADAMTS19 | c.2837T>G p.V946G | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV50735398; called by muse, mutect2, varscan2
- ASH2L | c.163C>T p.P55S | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.017); catalogued as rs1320603140, COSV51698806; called by muse, mutect2, varscan2
- BCO1 | c.515A>G p.H172R | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1324730047, COSV50728425; called by muse, mutect2, varscan2
- CD84 | c.736T>C p.F246L | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as rs749619938, COSV60867182; called by muse, mutect2, varscan2
- CNOT1 | c.479A>G p.Y160C | Missense Mutation (SNP) | VAF 98/348 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV57766510; called by muse, mutect2, varscan2
- CNTNAP3 | c.1792C>T p.R598* | Nonsense Mutation (SNP) | VAF 29/77 reads (38%) | catalogued as rs1339911236, COSV52665179; called by muse, mutect2, varscan2
- CPVL | c.358C>A p.L120I | Missense Mutation (SNP) | VAF 63/192 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.936); catalogued as COSV55300221; called by muse, varscan2
- DCC | c.1324A>T p.S442C | Missense Mutation (SNP) | VAF 73/220 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV59090595; called by muse, mutect2, varscan2
- DGKZ | c.3280G>T p.E1094* (on ENST00000454345 / NM_001105540.2; = p.E906* on NM_003646.4) | Nonsense Mutation (SNP) | VAF 4/12 reads (33%) | catalogued as COSV100552170; called by muse, mutect2, varscan2
- DMWD | c.553G>T p.G185C | Missense Mutation (SNP) | VAF 39/120 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV54288148; called by muse, mutect2, varscan2
- ERAP1 | c.418C>T p.L140F | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.049); catalogued as COSV57085961; called by muse, mutect2, varscan2
- FAM83H | c.667T>C p.S223P | Missense Mutation (SNP) | VAF 40/131 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV66353595; called by muse, mutect2, varscan2
- GMPS | c.1883A>T p.Q628L | Missense Mutation (SNP) | VAF 44/153 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV55808366; called by muse, mutect2, varscan2
- GNPTAB | c.3590A>G p.E1197G | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV54777866; called by muse, mutect2, varscan2
- GSTA2 | c.351A>T p.Q117H | Missense Mutation (SNP) | VAF 121/336 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.361); catalogued as COSV101534083, COSV72414697; called by muse, mutect2, varscan2
- IGLV1-47 | c.197T>C p.L66P | Missense Mutation (SNP) | VAF 71/207 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.097); catalogued as rs757894375; called by muse, mutect2, varscan2
- INVS | c.2947C>A p.P983T | Missense Mutation (SNP) | VAF 27/47 reads (57%) | SIFT tolerated, low confidence (0.94); PolyPhen benign (0); catalogued as COSV52439304; called by muse, mutect2, varscan2
- IQGAP1 | c.1919G>T p.G640V | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV51582608; called by muse, mutect2, varscan2
- ITGB4 | c.3441G>A p.W1147* | Nonsense Mutation (SNP) | VAF 44/83 reads (53%) | catalogued as COSV52322848; called by muse, mutect2, varscan2
- KBTBD6 | c.308G>A p.G103D | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65271022; called by muse, mutect2, varscan2
- KCNJ15 | c.1057_1059del p.E353del | In Frame Del (DEL) | VAF 16/60 reads (27%) | catalogued as rs1569023234; called by pindel, varscan2
- LAMA5 | c.734C>A p.S245Y | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53354903, COSV53374974; called by mutect2, varscan2
- LRBA | c.88G>T p.G30W | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.219); catalogued as COSV63951448; called by muse, mutect2, varscan2
- LY6G6F-LY6G6D | c.706A>T p.I236F | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.659); catalogued as COSV65442617; called by muse, mutect2, varscan2
- MED13 | c.4846A>C p.T1616P | Missense Mutation (SNP) | VAF 31/120 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.69); catalogued as COSV67262417; called by muse, mutect2, varscan2
- NKIRAS1 | c.151C>T p.R51* | Nonsense Mutation (SNP) | VAF 49/172 reads (28%) | catalogued as rs761150585, COSV66248104; called by muse, mutect2, varscan2
- PC | c.963C>A p.Y321* | Nonsense Mutation (SNP) | VAF 34/107 reads (32%) | catalogued as COSV63079448; called by muse, mutect2, varscan2
- PGAP1 | c.736G>A p.D246N | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV61324566; called by muse, mutect2, varscan2
- PRKG1 | c.567C>G p.N189K | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV64786453; called by muse, varscan2
- RASAL1 | c.172A>T p.T58S | Missense Mutation (SNP) | VAF 113/329 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.932); catalogued as COSV55654489; called by muse, mutect2, varscan2
- SACS | c.11021A>G p.N3674S | Missense Mutation (SNP) | VAF 38/95 reads (40%) | SIFT tolerated (0.44); PolyPhen benign (0.01); catalogued as rs1262552094, COSV66536315; called by muse, mutect2, varscan2
- SGSM3 | c.1538A>C p.K513T | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV50651381; called by muse, mutect2, varscan2
- SH2D3A | c.232T>C p.F78L | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.312); catalogued as COSV55585097; called by muse, mutect2, varscan2
- SLC27A1 | c.1834C>T p.R612C | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs149575978; called by muse, mutect2, varscan2
- TEX11 | c.1277G>A p.S426N (on ENST00000344304; = p.S411N on NM_031276.3) | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.113); catalogued as COSV60227637; called by muse, mutect2, varscan2
- ZHX2 | c.1721A>G p.D574G | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV58711148; called by muse, mutect2, varscan2
- ZNF613 | c.878G>T p.C293F (on ENST00000293471 / NM_001031721.4; = p.C257F on NM_024840.4) | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53271166; called by muse, varscan2
- CBR1 | c.205_214del p.S69Pfs*38 | Frame Shift Del (DEL) | VAF 14/56 reads (25%) | called by mutect2, pindel*
- CHRFAM7A | c.201del p.F69Lfs*8 | Frame Shift Del (DEL) | VAF 30/105 reads (29%) | called by mutect2, varscan2
- TBX3 | c.1252_1253del p.A418Cfs*2 (on ENST00000257566 / NM_016569.4; = p.A398Cfs*2 on NM_005996.4) | Frame Shift Del (DEL) | VAF 8/18 reads (44%) | called by mutect2, varscan2
- TMEM30A | c.358_359del p.M120Vfs*6 | Frame Shift Del (DEL) | VAF 11/32 reads (34%) | called by mutect2, pindel, varscan2
- TRIM2 | c.1580del p.G527Dfs*21 (on ENST00000437508; = p.G554Dfs*21 on NM_015271.5 and 4 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 43/132 reads (33%) | called by mutect2, pindel, varscan2
- ACTC1 | c.957C>A p.I319= | Silent (SNP) | VAF 108/310 reads (35%) | catalogued as COSV51757731, COSV51761470; called by muse, mutect2, varscan2
- ADRA2B | c.630G>A p.K210= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as COSV69787116, COSV69787279; called by muse, mutect2, varscan2
- DCAF1 | c.2802G>C p.R934= | Silent (SNP) | VAF 23/54 reads (43%) | catalogued as COSV60041353; called by muse, mutect2, varscan2
- EIF3E | c.1215T>A p.I405= | Silent (SNP) | VAF 38/102 reads (37%) | catalogued as COSV55201952; called by muse, mutect2, varscan2
- MAP2K7 | c.954A>G p.G318= | Silent (SNP) | VAF 11/39 reads (28%) | catalogued as COSV67607782; called by muse, mutect2, varscan2
- MAP3K13 | c.378C>T p.G126= | Silent (SNP) | VAF 25/83 reads (30%) | catalogued as COSV53985203; called by muse, mutect2, varscan2
- SPEN | c.5913T>C p.P1971= | Silent (SNP) | VAF 23/70 reads (33%) | catalogued as COSV65359021; called by muse, mutect2, varscan2
- WFS1 | c.1572C>T p.F524= | Silent (SNP) | VAF 71/174 reads (41%) | catalogued as COSV56988031; called by muse, mutect2, varscan2
- XRCC4 | c.192G>T p.G64= | Silent (SNP) | VAF 19/49 reads (39%) | catalogued as COSV56534348; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73851201 del AAACCCGCCATCTTTAACAATGCGGC | 3'Flank (DEL) | VAF 82/274 reads (30%) | catalogued as rs1410737257; called by mutect2, pindel, varscan2*
- ITIH5 | c.-1C>A | 5'UTR (SNP) | VAF 20/41 reads (49%) | catalogued as COSV99906194; called by muse, mutect2, varscan2
- LRRFIP1 | c.249+7103G>C | Intron (SNP) | VAF 55/160 reads (34%) | catalogued as COSV99791434; called by muse, mutect2, varscan2
- NXF5 | n.814A>T | RNA (SNP) | VAF 97/357 reads (27%) | catalogued as COSV53790150; called by muse, mutect2, varscan2
